Somatic mutation profile of tumor specimen ALCH-ABOZ-TTP1-A (aliquot ALCH-ABOZ-TTP1-A-1-0-D-A489-36) from ALCHEMIST case ALCH-ABOZ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 68.7 years (25,078 days).
Specimen ALCH-ABOZ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7733dc77-b901-4741-a790-eaba4579f5be.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ABOZ-NB1-A (Blood Derived Normal), aliquot ALCH-ABOZ-NB1-A-1-0-D-A489-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/82eecb66-16a6-4a65-9975-e41add120081

The open-access MAF lists 94 somatic variants for this specimen: 65 protein-altering or splice-affecting, 18 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 60, Silent 18, Intron 4, 5'Flank 3, Splice Site 3, 5'UTR 2, Nonsense Mutation 2, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANK1 | c.933G>T p.M311I | Missense Mutation (SNP) | VAF 25/486 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.163); catalogued as COSV55875682; called by muse, mutect2
- ATP7A | c.371C>A p.T124N | Missense Mutation (SNP) | VAF 12/276 reads (4%) | SIFT tolerated (0.66); PolyPhen benign (0.339); catalogued as COSV58452722; called by muse, mutect2
- CDH20 | c.49G>C p.G17R | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.149); catalogued as rs1445817526; called by muse, mutect2
- COL11A1 | c.2639G>T p.G880V | Missense Mutation (SNP) | VAF 28/462 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1011558820; called by muse, mutect2
- DUOX2 | c.3688G>T p.A1230S | Missense Mutation (SNP) | VAF 20/308 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.035); catalogued as rs1471293570; called by muse, mutect2
- ELK1 | c.497C>A p.S166Y | Missense Mutation (SNP) | VAF 17/333 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99901982; called by muse, mutect2
- ENOSF1 | c.905G>T p.R302L (on ENST00000340116 / NM_001354066.2; = p.R254L on NM_017512.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/152 reads (7%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.626); catalogued as rs1446158374; called by muse, mutect2
- HGF | c.895C>A p.P299T | Missense Mutation (SNP) | VAF 15/149 reads (10%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as COSV55946603, COSV55947003; called by muse, mutect2, varscan2
- KIAA1549L | c.2257A>G p.T753A (on ENST00000321505; = p.T1050A on NM_012194.3) | Missense Mutation (SNP) | VAF 20/319 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as COSV99684471; called by muse, mutect2
- NEU4 | c.606C>A p.S202R (on ENST00000391969 / NM_001167602.3; = p.S214R on NM_080741.4) | Missense Mutation (SNP) | VAF 19/272 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57991774; called by muse, mutect2
- NRXN1 | c.430C>G p.R144G | Missense Mutation (SNP) | VAF 27/534 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs1398835622; called by muse, mutect2
- PSD3 | c.22-1G>T p.X8_splice | Splice Site (SNP) | VAF 10/128 reads (8%) | catalogued as COSV58981112; called by muse, mutect2
- RBM10 | c.1435+1G>T p.X479_splice | Splice Site (SNP) | VAF 8/121 reads (7%) | catalogued as COSV61312299; called by muse, mutect2
- RGS13 | c.112T>G p.L38V | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.805); catalogued as COSV67345968; called by muse, mutect2
- RYR2 | c.5818C>A p.Q1940K | Missense Mutation (SNP) | VAF 27/224 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100768592; called by muse, mutect2, varscan2
- SH3TC2 | c.2527G>T p.G843* | Nonsense Mutation (SNP) | VAF 17/236 reads (7%) | catalogued as COSV60461696; called by muse, mutect2
- STOML1 | c.293C>T p.T98I | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.209); catalogued as COSV57551194; called by muse, mutect2
- TGM6 | c.543G>T p.Q181H | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1400950815; called by muse, mutect2
- TRIM64C | c.1276G>A p.G426S | Missense Mutation (SNP) | VAF 24/434 reads (6%) | SIFT tolerated (0.84); PolyPhen benign (0.033); catalogued as rs967518383; called by muse, mutect2
- ZNF98 | c.1100C>A p.T367K | Missense Mutation (SNP) | VAF 16/252 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV63337124; called by muse, mutect2
- ABCB4 | c.1671T>A p.D557E | Missense Mutation (SNP) | VAF 17/325 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- ACSL6 | c.1283T>A p.V428E (on ENST00000379240; = p.V453E on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.169); called by muse, mutect2
- ANK2 | c.698G>T p.G233V | Missense Mutation (SNP) | VAF 18/330 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CACNA1F | c.581G>A p.G194E | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.404); called by muse, mutect2
- CASQ1 | c.997T>A p.W333R | Missense Mutation (SNP) | VAF 9/163 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- DHX58 | c.1516G>T p.A506S | Missense Mutation (SNP) | VAF 11/191 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); called by muse, mutect2
- EPX | c.284T>A p.V95E | Missense Mutation (SNP) | VAF 20/349 reads (6%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.475); called by muse, mutect2
- EYS | c.4442G>T p.R1481I | Missense Mutation (SNP) | VAF 16/286 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2
- FAM53B | c.197G>C p.S66T | Missense Mutation (SNP) | VAF 8/169 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2
- FREM1 | c.556G>T p.G186C | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GABRA2 | c.779C>A p.P260H | Missense Mutation (SNP) | VAF 14/220 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GPRASP1 | c.3652G>A p.E1218K | Missense Mutation (SNP) | VAF 10/228 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.259); called by muse, mutect2
- KIAA1755 | c.2774C>G p.P925R | Missense Mutation (SNP) | VAF 13/294 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- KLHL2 | c.172G>T p.V58F | Missense Mutation (SNP) | VAF 15/253 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- LCT | c.2630C>A p.P877H | Missense Mutation (SNP) | VAF 15/204 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MUC16 | c.16870C>A p.P5624T | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.001); called by muse, mutect2
- MYO3A | c.2435T>A p.L812Q | Missense Mutation (SNP) | VAF 14/231 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- NCK2 | c.473G>T p.G158V | Missense Mutation (SNP) | VAF 11/133 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NCKAP5 | c.5060C>A p.A1687E | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT tolerated (0.56); PolyPhen benign (0.006); called by muse, mutect2
- NES | c.1268A>T p.Q423L | Missense Mutation (SNP) | VAF 15/333 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.06); called by muse, mutect2
- NUGGC | c.2048G>A p.C683Y | Missense Mutation (SNP) | VAF 11/152 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.014); called by muse, mutect2
- OR11L1 | c.791C>A p.P264H | Missense Mutation (SNP) | VAF 15/245 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.068); called by muse, mutect2
- OR13F1 | c.901T>A p.L301M | Missense Mutation (SNP) | VAF 15/199 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.001); called by muse, mutect2
- OR1A1 | c.475C>T p.H159Y | Missense Mutation (SNP) | VAF 18/192 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); called by muse, mutect2
- OR9A2 | c.421G>T p.V141L | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.544); called by muse, mutect2
- PIKFYVE | c.1468A>G p.N490D | Missense Mutation (SNP) | VAF 20/335 reads (6%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.152); called by muse, mutect2
- PLXNA4 | c.545A>T p.K182M | Missense Mutation (SNP) | VAF 16/326 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.568); called by muse, mutect2
- PPP2R2B | c.71-1G>C p.X24_splice (on ENST00000394409; = p.X90_splice on NM_181674.2) | Splice Site (SNP) | VAF 13/220 reads (6%) | called by muse, mutect2
- PUS1 | c.133G>T p.D45Y | Missense Mutation (SNP) | VAF 16/260 reads (6%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); called by muse, mutect2
- RAP1GAP | c.1096C>A p.L366M | Missense Mutation (SNP) | VAF 12/210 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.547); called by muse, mutect2
- RYR2 | c.5274G>T p.R1758S | Missense Mutation (SNP) | VAF 34/246 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- SCNN1G | c.451C>A p.Q151K | Missense Mutation (SNP) | VAF 20/360 reads (6%) | SIFT tolerated (0.89); PolyPhen benign (0); called by muse, mutect2
- SETBP1 | c.3624G>T p.E1208D | Missense Mutation (SNP) | VAF 36/752 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0.022); called by muse, mutect2
- SLITRK1 | c.1388T>A p.L463H | Missense Mutation (SNP) | VAF 7/114 reads (6%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.664); called by muse, mutect2
- SORCS1 | c.3247G>A p.A1083T | Missense Mutation (SNP) | VAF 9/184 reads (5%) | SIFT tolerated (0.41); PolyPhen benign (0.366); called by muse, mutect2
- TRPM8 | c.1756G>T p.G586C | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); called by muse, mutect2
- TSHZ3 | c.1691T>A p.L564Q | Missense Mutation (SNP) | VAF 15/197 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.259); called by muse, mutect2
- TSPYL1 | c.253G>A p.V85I | Missense Mutation (SNP) | VAF 22/254 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2
- TTN | c.59610C>G p.S19870R (on ENST00000591111; = p.S12446R on NM_003319.4) | Missense Mutation (SNP) | VAF 7/163 reads (4%) | PolyPhen possibly damaging (0.714); called by muse, mutect2
- XIRP2 | c.7402C>A p.H2468N (on ENST00000628543; = p.H2643N on NM_152381.6) | Missense Mutation (SNP) | VAF 16/254 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2
- ZDHHC9 | c.517G>T p.G173W | Missense Mutation (SNP) | VAF 22/342 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZEB2 | c.926C>T p.P309L | Missense Mutation (SNP) | VAF 16/175 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZNF300 | c.682A>T p.N228Y | Missense Mutation (SNP) | VAF 11/152 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ZNF711 | c.1082G>T p.R361M | Missense Mutation (SNP) | VAF 18/273 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); called by muse, mutect2
- ZNF792 | c.267T>G p.Y89* | Nonsense Mutation (SNP) | VAF 8/180 reads (4%) | called by muse, mutect2
- CDK5RAP2 | c.3681C>T p.I1227= | Silent (SNP) | VAF 12/205 reads (6%) | catalogued as COSV62572703; called by muse, mutect2
- CRACR2A | c.246A>T p.L82= | Silent (SNP) | VAF 21/205 reads (10%) | called by muse, mutect2, varscan2
- DICER1 | c.2142A>T p.P714= | Silent (SNP) | VAF 25/451 reads (6%) | called by muse, mutect2
- HDAC9 | c.2967G>C p.P989= | Silent (SNP) | VAF 10/99 reads (10%) | catalogued as COSV67770591; called by muse, mutect2
- HTR5A | c.582A>T p.V194= | Silent (SNP) | VAF 30/451 reads (7%) | called by muse, mutect2
- JPT2 | c.534G>T p.L178= | Silent (SNP) | VAF 8/131 reads (6%) | catalogued as COSV50189529; called by muse, mutect2
- LRRC7 | c.3324G>A p.L1108= (on ENST00000651989 / NM_001370785.2; = p.L1075= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 13/245 reads (5%) | called by muse, mutect2
- MINAR1 | c.2628A>G p.L876= | Silent (SNP) | VAF 18/392 reads (5%) | called by muse, mutect2
- MYOC | c.417G>A p.E139= | Silent (SNP) | VAF 20/329 reads (6%) | catalogued as COSV50680352; called by muse, mutect2
- OR2M4 | c.474A>T p.I158= | Silent (SNP) | VAF 26/153 reads (17%) | called by muse, mutect2, varscan2
- PNLIP | c.741A>T p.G247= | Silent (SNP) | VAF 7/120 reads (6%) | called by muse, mutect2
- PRAMEF10 | c.462C>T p.C154= | Silent (SNP) | VAF 15/254 reads (6%) | called by muse, mutect2
- SHANK2 | c.3636C>T p.P1212= | Silent (SNP) | VAF 20/420 reads (5%) | catalogued as COSV53599242; called by muse, mutect2
- SIKE1 | c.105G>A p.A35= | Silent (SNP) | VAF 23/400 reads (6%) | called by muse, mutect2
- SLC6A17 | c.2127C>T p.P709= | Silent (SNP) | VAF 8/110 reads (7%) | called by muse, mutect2
- TBX19 | c.1107A>T p.P369= | Silent (SNP) | VAF 24/390 reads (6%) | called by muse, mutect2
- UNC5D | c.2766T>A p.L922= | Silent (SNP) | VAF 29/473 reads (6%) | called by muse, mutect2
- ZNF468 | c.804G>A p.E268= | Silent (SNP) | VAF 17/149 reads (11%) | catalogued as rs1208703517; called by muse, mutect2, varscan2
- AC244517.10 | c.36-9181G>T | Intron (SNP) | VAF 48/838 reads (6%) | called by muse, mutect2
- C10orf143 | c.69+2406G>T | Intron (SNP) | VAF 20/362 reads (6%) | called by muse, mutect2
- DIO3 | chr14:101560266 C>T | 5'Flank (SNP) | VAF 15/134 reads (11%) | called by muse, mutect2
- EN1 | c.-3A>T | 5'UTR (SNP) | VAF 9/114 reads (8%) | called by muse, mutect2
- IGKV1-17 | c.-8G>C | 5'UTR (SNP) | VAF 22/371 reads (6%) | called by muse, mutect2
- LIPG | c.*29G>A | 3'UTR (SNP) | VAF 18/282 reads (6%) | catalogued as rs1169098253; called by muse, mutect2
- MIR124-2 | chr8:64378164 G>C | 5'Flank (SNP) | VAF 10/148 reads (7%) | called by muse, mutect2
- MZT2B | chr2:130181825 G>C | 5'Flank (SNP) | VAF 9/136 reads (7%) | called by muse, mutect2
- OR51F5P | n.577G>T | RNA (SNP) | VAF 12/173 reads (7%) | called by muse, mutect2
- RSU1 | c.598+25467A>C | Intron (SNP) | VAF 6/120 reads (5%) | called by muse, mutect2
- TFCP2 | c.123-6157G>T | Intron (SNP) | VAF 30/422 reads (7%) | called by muse, mutect2
